Surgical pathology report (de-identified scan), TCGA case TCGA-HB-A3YV, project TCGA-SARC (Sarcoma), tissue source site University of North Carolina, specimen TCGA-HB-A3YV-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY

Case Number :

Surgical Pathology Report

Addenda Present

Accession #: ...

Tumor Malignancy History		☒

6/6/12

Diagnosis:

A: Kidney, left, radical nephrectomy

Histologic tumor type/subtype: High grade pleomorphic sarcoma, see comment

Tumor grade (FNCLCC system): Grade 3

Tumor differentiation score: 3

Tumor necrosis score: 1

Mitotic count score: 3 (up to 21 mitoses in 10 high powered fields)

Total score: 7

Tumor size (greatest dimension): 14. cm

Tumor focality: Unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: microscopic invasion present

(focally on slides A15, A17, A19)

Renal sinus: Not involved

Major veins (renal vein or segmental branches, IVC): Not involved

Ureter: Not involved

Venous (large vessel): Not involved

Lymphatic (small vessel): Present (slide A4)

Histologic assessment of surgical margins:

Gerota's fascia (nephrectomy): within 1 mm of the blue inked perinephric margin (slides A17 and A19), tumor also focally extends to ink in

the area of disruption, see comment

Renal vein (nephrectomy): Negative for tumor

Ureter (nephrectomy): Negative for tumor

ICD-O3
Sarcoma, pleomorphic
8802/3
Site: CACF-retroperitoneum
C48.0
PATH-KIDNEY, NOS C64.9
6-6-12
RD

[page 2 of 6]
Adrenal gland: Involved by tumor through direct extension

Lymph nodes: Not resected

AJCC Staging (staged for a soft tissue sarcoma):

pT2b

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Soft tissue, superior medial margin, biopsy

- Benign fibroadipose tissue with hemorrhage, focal acute inflammation, and focal fat necrosis
- No malignancy identified

Comment:

The tumor is a high grade pleomorphic sarcoma involving the upper pole of the kidney. While the tumor appears mostly confined to the kidney, the tumor focally invades through the renal capsule to involve perinephric fat, and is very close (within 1 mm) to the Gerota's fascia/perinephric fat margin. The tumor also abuts the adrenal gland, and involves the medulla of the adrenal gland through direct extension. The superior medial aspect of the tumor was partially disrupted, and tumor focally extends to ink in the area of disruption.

The differential diagnosis for this high grade sarcoma includes dedifferentiated liposarcoma and pleomorphic leiomyosarcoma. The tumor is positive for desmin, CD34, CD10, and vimentin, results which are non-specific and may be seen in either tumor type. There are focal abnormal cells within the fatty tissue and fibrous bands adjacent to the sarcoma (slides A17 and A19), which raises the

[page 3 of 6]
possibility of dedifferentiated liposarcoma, but the majority of the perinephric fat does not appear abnormal. Smooth muscle actin and CD31 stains highlight prominent blood and lymphatic vessels within the tumor, but do not stain the tumor cells. The tumor is negative for cytokeratins AE1/AE3, CK 8/18, and RCC lending no support for a diagnosis of sarcomatoid renal cell carcinoma. The tumor is negative for S100, synaptophysin, and chromogranin, indicating that the tumor is not of nerve or adrenal medullary origin. The tumor is also negative for calponin, c-kit, and HMB45, lending no support for GIST or angiomyolipoma. While primary renal sarcomas are rare, leiomyosarcoma is the most common primary renal sarcoma. Liposarcomas involving the kidney most often arise in the retroperitoneum and secondarily involve the kidney, but primary renal liposarcomas have been reported.

Referral testing for MDM2 gene amplification testing is being requested and the results will be reported in an addendum. MDM2 is amplified in well-differentiated liposarcomas and some dedifferentiated liposarcomas, and may be helpful in determining if the sarcoma has an adipocytic origin.

The case was discussed with Dr. on Drs. and have reviewed the case and agree with the diagnosis of high grade pleomorphic sarcoma.

Clinical History:

-year-old with a left renal mass.

Gross Description:

Received are two appropriately labeled containers.

[page 4 of 6]
Specimen A:

Specimen fixation: Formalin

Type of specimen: Nephrectomy

Side of specimen: Left

Size and weight of specimen: 1,720 grams, 29 x 19 x 10 cm overall with a 15 x 9 x 9 cm kidney, 8 cm of attached ureter and abundant attached perinephric fat.

Orientation: The external surface is inked blue and there is a 6 cm full thickness defect exuding tumor tissue along the superior medial aspect of the specimen. The edges of this defect are marked with yellow ink for identification purposes.

Presence/absence of adrenal gland: Adrenal gland is present (5.7 x 2.0 x 0.5 cm)

Tumor site: The tumor is present in the superior pole and extends medially and superiorly.

Tumor description: The tumor is a fleshy gray/tan friable mass lining a dominant cyst. The edges of the cyst are focally fleshy and more solid appearing. The tumor has a markedly mucinous component.

Tumor size: 14 x 11 x 10 cm

Presence/absence of multicentricity: Absent

Confinement/non-confinement to the kidney: Indeterminate due to the disrupted nature of the superior medial aspect. The tumor appears partially encapsulated and well-demarcated from the perinephric fat and adjacent renal parenchyma of the inferior pole.

Extent of invasion:

[page 5 of 6]
Perirenal adipose tissue: Tumor grossly does not involve

Gerota' s fascia: Tumor grossly does not involve.

Renal vein: Tumor grossly does not involve.

Ureter: Tumor grossly does not involve.

Renal Sinus: Tumor grossly does not involve.

Pelvicaliceal: Tumor grossly does not involve.

Adrenal: Tumor grossly involves the medulla of the adrenal. The adrenal cortex is a thin rim of orange parenchyma and unremarkable. Tumor grossly abuts the adrenal gland.

Other organs: N/A

Surgical margins:

Perirenal adipose tissue: Within <0.1 cm of the blue inked surgical margin.

Renal vein: Negative

Renal artery: Focally encased at the hilum but negative.

Ureter: Negative

Description of kidney away from tumor: Gray/tan with a cortical thickness of 0.8 cm.

Hilar lymph nodes: None identified.

Other significant findings: None.

Tissue submitted for special investigations: Tumor and normal are given to tissue procurement.

Digital picture: No

Block Summary:

[page 6 of 6]
A1 - Ureter and vascular margins of resection, en face
A2-A4 - Tumor involving adrenal
A5-A6 - Tumor and overlying inked surgical margin
A7 - Tumor around renal artery
A8 - Tumor and perinephric fat
A9 - Tumor and renal sinus
A10 - Normal kidney
A11 - Kidney and tumor interface
A12-A14 - Representative sections of tumor (A14 contains tumor
in
relationship to full thickness defect)
A15-A16 - Additional sections of tumor at yellow inked
superior/medial
defect
A17-A23 - Tumor expanding renal capsule
A24-A25 - Tumor and adrenal
A26-A27 - Tumor and blue ink

Container B is additionally labeled "superior medial margin" and
is an irregular
and unoriented 3.2 x 1.7 x 1.0 cm fragment of hemorrhagic fat,
serially
sectioned and entirely submitted in block B1,

Procedures/Addenda:
Addendum

Addendum
Addendum for specimen A:

Addendum Comment
Fluorescence in situ hybridization (FISH) for MDM2 gene
amplification was
performed at --- on the tumor tissue (slide A13).
The FISH
results show an MDM2 amplification with an MDM2/SE12 ratio of
2.71. Per their
protocol, MDM2/SE12 ratios greater than 2.0 are considered
amplified. While
FISH for MDM2 gene amplification is intended to differentiate
well-differentiated liposarcomas/atypical lipomatous tumors from
lipomas, gene
amplification in this tumor suggests that this tumor has
lipocytic
differentiation.

Source: NCI Genomic Data Commons file a36e2591-728f-4ddd-b0bd-8928356a5dd1 (TCGA-HB-A3YV.4A29D95A-86DA-4A05-90F6-00B45D2D08D1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).